Somatic mutation profile of tumor specimen TCGA-CV-A6JY-01A (aliquot TCGA-CV-A6JY-01A-11D-A31L-08) from TCGA case TCGA-CV-A6JY, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 69.3 years (25,321 days).
Specimen TCGA-CV-A6JY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3acc36b-ee2b-46b8-a31b-960e8639c3d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A6JY-10A (Blood Derived Normal), aliquot TCGA-CV-A6JY-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b54c0bd0-4569-4189-b5f6-d0fa40ed2ae7

The open-access MAF lists 82 somatic variants for this specimen: 68 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 13, Nonsense Mutation 6, Splice Site 1, Frame Shift Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as rs373221034, COSV60102332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs372010773; called by muse, mutect2
- AFDN | c.4480G>A p.D1494N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100652445; called by muse, mutect2, varscan2
- AHNAK | c.5860C>T p.P1954S | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99945531; called by muse, mutect2
- ANAPC1 | c.5138T>C p.M1713T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV100594508; called by mutect2, varscan2
- ANKDD1A | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV100731061; called by muse, mutect2, varscan2
- ARSB | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99364309, COSV99364650; called by muse, mutect2
- C2orf88 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100502684; called by muse, mutect2, varscan2
- C9 | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99661662; called by muse, mutect2
- CACNA1G | c.4556C>T p.S1519L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1369181328, COSV100661134; called by muse, mutect2, varscan2
- CD1C | c.434A>G p.Q145R | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs1385386776, COSV100939350; called by muse, mutect2
- CDK15 | c.443G>A p.R148Q (on ENST00000652192 / NM_001366386.2; = p.R97Q on NM_139158.2) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370446004; called by mutect2, varscan2
- CDRT1 | c.1953A>G p.I651M | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1274480550, COSV100599735; called by muse, mutect2
- CFAP251 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754046262, COSV99995700; called by muse, mutect2, varscan2
- CHD6 | c.6301C>G p.L2101V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV100950545; called by muse, mutect2, varscan2
- COG2 | c.1555G>T p.D519Y | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794599; called by muse, mutect2, varscan2
- COL11A1 | c.4609-2A>T p.X1537_splice | Splice Site (SNP) | VAF 24/85 reads (28%) | catalogued as COSV100615080; called by muse, mutect2, varscan2
- CPEB2 | c.2828T>A p.L943H | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99469829; called by muse, mutect2, varscan2
- CUBN | c.2517A>T p.E839D | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.11); catalogued as COSV100912041; called by muse, mutect2, varscan2
- DCAF12L2 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775259004, COSV63580943; called by muse, mutect2, varscan2
- DEFB129 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV55731783, COSV99857336; called by muse, mutect2, varscan2
- DLX6 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs201772433; called by muse, mutect2, varscan2
- DUSP5 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.913); catalogued as rs374689886; called by muse, mutect2
- FBN2 | c.6600G>T p.M2200I | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV99324915; called by muse, mutect2, varscan2
- FBXO27 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.887); catalogued as COSV53072305, COSV53072898; called by muse, mutect2, varscan2
- GPATCH8 | c.2946G>A p.W982* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV59199422; called by muse, mutect2, varscan2
- GPBP1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.897); catalogued as rs775619360, COSV99302385; called by muse, mutect2, varscan2
- GPC3 | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV100892675; called by muse, mutect2, varscan2
- IL19 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765338474, COSV99536195; called by muse, mutect2, varscan2
- IL2 | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV99900715; called by muse, mutect2, varscan2
- IQCD | c.720G>T p.R240S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV100232250; called by muse, mutect2, varscan2
- KIF1A | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.876); catalogued as rs1236829353, COSV100239812; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KPNA6 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65362356; called by muse, mutect2, varscan2
- LRRC37B | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 26/94 reads (28%) | catalogued as COSV100496006; called by muse, mutect2, varscan2
- MACF1 | c.20873G>A p.R6958H (on ENST00000372915; = p.R5003H on NM_012090.5) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as rs188161549, COSV57152689; called by mutect2, varscan2
- MARCHF2 | c.435C>A p.F145L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV99294661; called by muse, mutect2, varscan2
- MCF2L2 | c.2732G>A p.R911H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs781608777, COSV61059012; called by muse, mutect2, varscan2
- MECOM | c.1811G>A p.R604Q (on ENST00000468789 / NM_001105078.4; = p.R792Q on NM_004991.4) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs753395114, COSV52961431; called by muse, mutect2, varscan2
- MEI1 | c.3457C>T p.R1153W | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1308374741, COSV100299585; called by muse, mutect2
- MUC3A | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.17); catalogued as rs781659697, COSV60212876; called by mutect2, varscan2
- MYCBPAP | c.322C>G p.P108A | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100087654; called by muse, mutect2, varscan2
- NFKBID | c.881C>T p.P294L (on ENST00000396901; = p.P446L on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV100573191; called by muse, mutect2
- NLRP5 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1304132572, COSV101173364; called by muse, mutect2
- OBP2A | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs760517173, COSV59790956, COSV59791163; called by muse, mutect2, varscan2
- OR4C6 | c.374G>T p.C125F | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV100051391; called by muse, mutect2
- OR9G1 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs202001195; called by muse, mutect2
- PAN2 | c.2932G>A p.D978N (on ENST00000425394 / NM_001127460.3; = p.D974N on NM_014871.5) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99228095; called by muse, mutect2, varscan2
- PPARGC1B | c.2939G>A p.R980Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs769619393, COSV58529438; called by muse, mutect2, varscan2
- PSMA5 | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99600404; called by muse, mutect2, varscan2
- PTBP2 | c.1049T>C p.V350A (on ENST00000426398 / NM_001300986.2; = p.V342A on NM_021190.4) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV100930164; called by muse, mutect2
- RASGRF2 | c.2352A>G p.I784M | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as COSV99428504; called by muse, mutect2, varscan2
- SEMA4G | c.911G>C p.G304A | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV99271903; called by muse, mutect2
- SENP6 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs773071793, COSV59189455; called by muse, mutect2, varscan2
- SEZ6 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100252648; called by muse, mutect2, varscan2
- SLC39A12 | c.1100A>T p.Y367F | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV101069834; called by muse, mutect2, varscan2
- TENM1 | c.4549C>T p.R1517* | Nonsense Mutation (SNP) | VAF 33/67 reads (49%) | catalogued as rs759635160, COSV100949007; called by muse, mutect2, varscan2
- TKFC | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as rs112089652; called by muse, mutect2, varscan2
- VCAN | c.5990C>A p.S1997* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as COSV99424625; called by muse, mutect2, varscan2
- WWC1 | c.3148C>T p.R1050W | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs138503526, COSV54652229; called by muse, mutect2
- XPO6 | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as COSV100484662; called by muse, mutect2
- ZBTB45 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.546); catalogued as rs200526639, COSV63525010; called by muse, mutect2, varscan2
- ZIC4 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101267822; called by muse, mutect2, varscan2
- ZMYND11 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100555847, COSV59077651; called by muse, mutect2, varscan2
- FBXW7 | c.1150_1169del p.I384Wfs*2 (on ENST00000281708 / NM_001349798.2; = p.I304Wfs*2 on NM_018315.5) | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel
- SENP2 | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2
- TAF15 | c.1594G>T p.G532* (on ENST00000605844 / NM_139215.3; = p.G529* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 26/104 reads (25%) | called by muse, mutect2, varscan2
- TAF15 | c.1595G>T p.G532V (on ENST00000605844 / NM_139215.3; = p.G529V on NM_003487.4) | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- TP53 | c.434dup p.W146Vfs*3 | Frame Shift Ins (INS) | VAF 17/56 reads (30%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.10065C>T p.D3355= | Silent (SNP) | VAF 36/236 reads (15%) | catalogued as rs760268875, COSV100315542, COSV60914561; called by muse, mutect2, varscan2
- BEND4 | c.1164G>A p.L388= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as COSV72469008; called by muse, mutect2, varscan2
- BRINP2 | c.51C>G p.A17= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100837825; called by muse, mutect2, varscan2
- CCDC180 | c.984C>T p.I328= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs1274410681, COSV100826552, COSV63829806; called by muse, mutect2, varscan2
- ITSN2 | c.2373A>T p.V791= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100742650; called by muse, mutect2, varscan2
- LRRTM1 | c.174C>T p.T58= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs1439942630, COSV54444764, COSV99701781; called by muse, mutect2, varscan2
- MAP4K4 | c.1698G>T p.A566= (on ENST00000347699 / NM_001242559.2; = p.A535= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs367609543, COSV100153422; called by muse, mutect2
- MED1 | c.3450G>A p.G1150= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100327372; called by muse, mutect2
- NTHL1 | c.938G>A p.*313= (on ENST00000219066; = p.*305= on NM_002528.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99526098; called by muse, mutect2, varscan2
- OR4L1 | c.291C>T p.C97= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as rs375250646; called by muse, mutect2, varscan2
- OTOP1 | c.756T>C p.C252= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV99587341; called by muse, mutect2, varscan2
- PLEKHF2 | c.604C>A p.R202= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV100193329, COSV59542062; called by muse, mutect2, varscan2
- PTGES2 | c.972C>T p.F324= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as COSV99476233; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85883C>T | Intron (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
